Gene-level copy-number profile of tumor specimen TCGA-AP-A1DQ-01A from TCGA case TCGA-AP-A1DQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,815 days).
Specimen TCGA-AP-A1DQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.7810f823-458a-45e4-909a-e87c29f96449.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A1DQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13122301-e85f-4936-b705-f7be74fe46c3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,761; copy number 2: 13,221; copy number 3: 25,457; copy number 4: 17,003; copy number 5: 1,227; copy number 6: 981; copy number 7: 143; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A1DQ-01A-11D-A134-01): tumor purity 0.58, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:8,474,207–8,630,761, 1 gene (within-gene range 0–2): MYH10.
- chr17:8,560,471–8,976,995, 9 genes: PPIAP52, AC025518.1, CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 151 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:121,954,640–129,683,770, 128 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:5,364,966–5,763,740, 15 genes, copy number 7 (within-gene range 4–7): UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1.
- chr10:15,075,475–15,171,278, 7 genes, copy number 9: ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1.
- chr10:15,237,492–15,241,767, 1 gene, copy number 9: AL607028.1.

Autosomal genes at a single copy (total copy number 1): 1,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
